Gene-level copy-number profile of specimen HCM-CSHL-0243-C18-85A from HCMI case HCM-CSHL-0243-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,279 days).
Specimen HCM-CSHL-0243-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c9d003b-79b5-4227-9701-5c237d6bba61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0243-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/72915ddc-9566-4d53-b8f1-c00b809c83e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,019; copy number 2: 49,365; copy number 3: 3,013; copy number 4: 2,512; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,513,176–161,605,099, 1 gene, copy number 6 (within-gene range 4–6): AL590385.2.
- chr1:161,581,339–161,678,654, 5 genes, copy number 6 (within-gene range 4–6): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B.

Autosomal genes at a single copy (total copy number 1): 1,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
